Somatic mutation profile of tumor specimen MP2PRT-PANYNM-TMP1-A (aliquot MP2PRT-PANYNM-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANYNM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,311 days).
Specimen MP2PRT-PANYNM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ac2002a-1073-4f70-9b39-cd47ef9f8b0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANYNM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANYNM-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0f967f0-d414-4b84-9eab-b7ff092aad57

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH19 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50967650; called by muse, mutect2, varscan2
- DAGLA | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 335/753 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs751323265; called by muse, mutect2, varscan2
- EPHA10 | c.807C>A p.C269* | Nonsense Mutation (SNP) | VAF 419/905 reads (46%) | catalogued as COSV57627871; called by muse, mutect2, varscan2
- FLNC | c.3022C>T p.R1008C | Missense Mutation (SNP) | VAF 367/845 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs757969015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MICAL3 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs374730406; called by muse, mutect2, varscan2
- OR6K2 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs754097354; called by muse, mutect2, varscan2
- PPA2 | c.267G>A p.E89= | Splice Region (SNP) | VAF 5/41 reads (12%) | catalogued as rs1191610321; called by muse, varscan2
- TCHH | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 153/518 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs1283851813, COSV64273721; called by muse, mutect2, varscan2
- CRYBG3 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- DBR1 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FBLN7 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 65/514 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IGHV3-53 | c.348_349insCCCCCGG | In Frame Ins (INS) | VAF 2/21 reads (10%) | called by mutect2, pindel*
- PATL1 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PNLIPRP2 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- RIMBP2 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 257/542 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SI | c.5412C>G p.N1804K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, varscan2
- TCHH | c.3231G>C p.E1077D | Missense Mutation (SNP) | VAF 135/567 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRANK1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TRIO | c.5635A>G p.S1879G | Missense Mutation (SNP) | VAF 49/598 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZBED1 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 106/1023 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHB1 | c.1851T>A p.S617= | Silent (SNP) | VAF 88/404 reads (22%) | called by muse, mutect2, varscan2
- HPCA | c.180C>T p.D60= | Silent (SNP) | VAF 202/483 reads (42%) | catalogued as rs555055449, COSV65102815; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHC1 | c.1473G>A p.G491= (on ENST00000368445 / NM_183001.5; = p.G382= on NM_003029.5) | Silent (SNP) | VAF 258/550 reads (47%) | called by muse, mutect2, varscan2
